Surgical pathology report (de-identified scan), TCGA case TCGA-44-6775, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-6775-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Date Coll: [REDACTED]

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. R4 lymph node
- B. Level 10 lymph node
- C. Right lobe stitch marks probably _____
- D. R4 lymph node
- E. Level 7 lymph node

CLINICAL NOTES

--

FROZEN SECTION DIAGNOSIS

- A) R4 lymph node, biopsy: Negative for carcinoma. [REDACTED]

GROSS DESCRIPTION

A. The specimen is received unfixed labeled "R4 lymph node" and consists of multiple pieces of red and black soft tissue measuring 1.8 x 1.7 x 0.3 cm. in aggregate. The entire n is submitted for frozen section diagnosis as requested.

[REDACTED] B. Specimen is received unfixed labeled "level 10 lymph node." Specimen is received unfixed and consists of two pieces of pink and red soft tissue measuring 2 x 0.7 x 0.4 cm in aggregate. AS-1.

C. The specimen is received unfixed labeled "right lobe" and consist of 175 gram lung lobe with a stapled margin. The specimen measures 12 x 8.5 x 6 cm. The pleural surface has a clefted appearance and there is a central firm area by palpation. On cut section there is a central firm white mass, the white area measures 4 by approximately 3 cm. In cross sectional dimension, a portion of this area may be peritumoral change. A portion of n is taken for research purposes. Sections after fixation.

[REDACTED]

Block summary: 1-bronchial and vascular margin of resection, 2-next level of bronchus and vessels, 3-4 tumor, 5,6 pulmonary margin, 7-11 tumor

D. Specimen is received unfixed labeled "R4 lymph node" and consists of a piece of black and red soft tissue measuring 1 x 0.4 x 0.7 cm. AS-1.

E. Specimen is received unfixed labeled "level 7 lymph node" and consists of multiple pieces of red and black soft tissue occupying approximately 2.5 mL in volume. AS-2.

[REDACTED]

[page 2 of 2]
- Tumor type: Adenocarcinoma
Tumor grade: 2
Mitotic Index: 12 mitoses/10 HPFs (1 HPF = 0.19 sq mm)
Tumor size: 4 cm
Bronchial resection margin: Negative for malignancy
Pulmonary margin of resection: Negative for malignancy
Pleura: Negative for malignancy
Vascular invasion: Absent
Attached lymph nodes: There is no evidence of malignancy in
one peribronchial lymph node
pTNM Stage: T2a
Non-tumorous lung: Unremarkable.

- ## DIAGNOSIS

- A. Lymph node, R4, biopsy: Negative for malignancy
B. Lymph node, level X, biopsy: There is no evidence of malignancy in either of 2 lymph nodes
C. Lung, right lobe, resection: Moderately well-differentiated adenocarcinoma
D. Lymph node, R4, biopsy: A single lymph node is negative for malignancy
E. Lymph node, level VII, biopsy: Negative for malignancy

--- End Of Report ---

Source: NCI Genomic Data Commons file fcd3391f-7ea8-4d03-9d3c-1ba6a5afc0b5 (TCGA-44-6775.CD641541-F607-49DE-8F57-FA54B0561721.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).